Somatic mutation profile of tumor specimen TARGET-10-PARDDW-09A (aliquot TARGET-10-PARDDW-09A-01D) from TARGET case TARGET-10-PARDDW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,626 days).
Specimen TARGET-10-PARDDW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89cc2ca6-7809-4f4e-abe8-61f08fb338f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDDW-10A (Blood Derived Normal), aliquot TARGET-10-PARDDW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32a3b3e4-b9ba-410c-bb66-2f396987eab1

The open-access MAF lists 72 somatic variants for this specimen: 50 protein-altering or splice-affecting, 11 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 11, Intron 7, RNA 2, In Frame Ins 1, 3'UTR 1, 3'Flank 1, Frame Shift Del 1, Splice Site 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 14/74 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 7/70 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ABLIM1 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 59/111 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs771927361, COSV53310921; called by muse, mutect2, varscan2
- ANKRD30B | c.961G>A p.G321R | Missense Mutation (SNP) | VAF 80/198 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV100745777; called by muse, varscan2
- ATF6 | c.1892C>T p.S631L | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771212825, COSV63406819; called by muse, mutect2, varscan2
- BSND | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 70/132 reads (53%) | SIFT tolerated (0.54); PolyPhen benign (0.177); catalogued as COSV64871324; called by muse, mutect2, varscan2
- C1orf198 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1467458781; called by muse, mutect2, varscan2
- CLTRN | c.584G>A p.G195D | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs1468901288; called by muse, mutect2, varscan2
- CPB1 | c.572G>A p.R191K | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs867912539, COSV51574151; called by muse, mutect2, varscan2
- CSMD2 | c.3598G>A p.E1200K | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.403); catalogued as COSV99588820; called by muse, mutect2, varscan2
- EOMES | c.2056C>T p.P686S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as rs1246146149; called by muse, mutect2, varscan2
- IMPA2 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 28/97 reads (29%) | catalogued as rs907860651; called by muse, mutect2, varscan2
- KLK3 | c.323A>G p.N108S | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.124); catalogued as rs747600000; called by muse, mutect2
- MPDZ | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV59937853; called by muse, mutect2, varscan2
- OGDHL | c.56T>G p.L19R | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1451073881; called by muse, mutect2, varscan2
- OR2AT4 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs267603189, COSV59406334; called by muse, mutect2, varscan2
- OR4X1 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201997353, COSV60723840; called by muse, mutect2, varscan2
- OR8I2 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs183167361, COSV100135978; called by muse, mutect2, varscan2
- RYR2 | c.13031G>A p.G4344E | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.259); catalogued as rs376433496; called by muse, mutect2, varscan2
- SETD5 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56707707; called by muse, mutect2, varscan2
- SLC17A8 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1342040241; called by muse, mutect2, varscan2
- TTLL6 | c.1351G>A p.E451K (on ENST00000393382 / NM_001130918.3; = p.E144K on NM_173623.3) | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs763618480; called by muse, mutect2, varscan2
- USP47 | c.3529C>T p.R1177C (on ENST00000399455 / NM_001372095.1; = p.R1089C on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1166025059, COSV59693969; called by muse, mutect2, varscan2
- VWDE | c.2458G>A p.G820R | Missense Mutation (SNP) | VAF 65/141 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51724237; called by muse, mutect2, varscan2
- WDR81 | c.5804G>A p.G1935E (on ENST00000409644 / NM_001163809.2; = p.G884E on NM_152348.4) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1476256003; called by muse, mutect2, varscan2
- ALG12 | c.640G>T p.V214F | Missense Mutation (SNP) | VAF 20/52 reads (38%) | PolyPhen benign (0.259); called by muse, mutect2, varscan2
- ANKRD30B | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 82/200 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.427); called by muse, varscan2
- ATF7IP | c.2811_2814del p.N937Kfs*3 | Frame Shift Del (DEL) | VAF 29/55 reads (53%) | called by pindel, varscan2
- BEX5 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- CCL20 | c.276A>T p.K92N | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- CNOT2 | c.426_430dup p.Q144Pfs*17 | Frame Shift Ins (INS) | VAF 47/126 reads (37%) | called by mutect2, pindel, varscan2
- CPZ | c.1573G>A p.V525I (on ENST00000360986 / NM_001014447.3; = p.V514I on NM_003652.3) | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- CYP39A1 | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHA6 | c.822A>C p.E274D | Missense Mutation (SNP) | VAF 69/165 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- F5 | c.1644_1645insAGT p.F548_A549insS | In Frame Ins (INS) | VAF 44/123 reads (36%) | called by mutect2, pindel, varscan2
- FCGBP | c.12131C>T p.T4044I | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FLG | c.9266C>T p.S3089F | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- IGKV2D-24 | chr2:90005628 CTCA>TCTTC | Missense Mutation (INS) | VAF 47/55 reads (85%) | called by pindel, varscan2*
- KANK2 | c.2021C>T p.S674F (on ENST00000586659 / NM_001379562.1; = p.S682F on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, varscan2
- NCKAP5L | c.3649+2T>G p.X1217_splice | Splice Site (SNP) | VAF 26/50 reads (52%) | called by muse, mutect2, varscan2
- NFIX | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PHKA1 | c.3428A>C p.H1143P | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHKA1 | c.2212C>T p.P738S | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- PJA1 | c.1343C>T p.S448F (on ENST00000361478 / NM_145119.4; = p.S260F on NM_022368.5) | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- PLAT | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- PLIN4 | c.1852G>A p.D618N (on ENST00000301286; = p.D633N on NM_001367868.2) | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- SCN3A | c.2795C>G p.S932C | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM229A | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZAR1L | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ZEB2 | c.3286C>T p.R1096C | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- APOL4 | c.456C>T p.I152= (on ENST00000352371 / NM_145660.2; = p.I149= on NM_030643.4) | Silent (SNP) | VAF 73/156 reads (47%) | called by muse, mutect2, varscan2
- ASXL1 | c.1248C>T p.L416= | Silent (SNP) | VAF 40/89 reads (45%) | catalogued as rs1370030998, COSV60103277; called by muse, mutect2, varscan2
- COL5A2 | c.4332C>T p.I1444= | Silent (SNP) | VAF 60/150 reads (40%) | catalogued as rs138837670; called by muse, mutect2, varscan2
- EPRS1 | c.3762C>T p.I1254= | Silent (SNP) | VAF 32/64 reads (50%) | catalogued as rs537386099, COSV65098475; called by muse, mutect2, varscan2
- FKBP10 | c.681G>A p.R227= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as rs371862066, COSV58636743; called by muse, mutect2, varscan2
- PLG | c.342G>A p.T114= | Silent (SNP) | VAF 58/119 reads (49%) | catalogued as rs776970597, COSV51980374; called by muse, mutect2, varscan2
- RYR2 | c.9189C>T p.N3063= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as rs531651646, COSV63685011; ClinVar: likely benign; called by muse, mutect2, varscan2
- RYR2 | c.13929C>T p.N4643= | Silent (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- SCN3A | c.2796C>T p.S932= | Silent (SNP) | VAF 21/101 reads (21%) | catalogued as rs1257592729; called by muse, mutect2, varscan2
- SLC34A2 | c.1747C>T p.L583= | Silent (SNP) | VAF 31/78 reads (40%) | called by muse, mutect2, varscan2
- TMEM89 | c.366C>T p.L122= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as rs868602873, COSV56570281; called by muse, mutect2, varscan2
- AC109583.1 | c.-1319+1916G>C | Intron (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- BOD1P2 | n.24C>T | RNA (SNP) | VAF 12/20 reads (60%) | called by muse, mutect2, varscan2
- CDKL1 | c.172-3804_172-3803insCTTGAGC | Intron (INS) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- DLX4 | c.480+62C>T | Intron (SNP) | VAF 26/77 reads (34%) | called by muse, mutect2, varscan2
- DNAJC2 | c.1529-21T>G | Intron (SNP) | VAF 18/41 reads (44%) | called by muse, mutect2, varscan2
- GRM7 | c.519+993G>A | Intron (SNP) | VAF 32/64 reads (50%) | called by muse, mutect2, varscan2
- IL31RA | c.*87C>T | 3'UTR (SNP) | VAF 35/75 reads (47%) | called by muse, mutect2, varscan2
- MIR5197 | n.48G>A | RNA (SNP) | VAF 64/147 reads (44%) | called by muse, mutect2, varscan2
- MTND6P20 | chr8:46843583 C>T | 3'Flank (SNP) | VAF 10/26 reads (38%) | catalogued as rs1261836900; called by muse, varscan2
- UGT1A6 | c.862-23370C>T | Intron (SNP) | VAF 36/89 reads (40%) | called by muse, mutect2, varscan2
- WRAP73 | c.604-29C>T | Intron (SNP) | VAF 7/61 reads (11%) | catalogued as rs1410530421; called by muse, mutect2, varscan2
